Somatic mutation profile of tumor specimen TCGA-IW-A3M6-01A (aliquot TCGA-IW-A3M6-01A-11D-A21Q-09) from TCGA case TCGA-IW-A3M6, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 59.3 years (21,674 days).
Specimen TCGA-IW-A3M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1377608b-b44f-4572-81da-686fd6c44577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IW-A3M6-10A (Blood Derived Normal), aliquot TCGA-IW-A3M6-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/726632dc-11b6-4ab4-ab55-23d3cf3a78e4

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, RNA 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.207); catalogued as COSV100040976; called by muse, mutect2, varscan2
- AMACR | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100162785; called by muse, mutect2
- ANKRD55 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs141966247; called by muse, mutect2, varscan2
- ATM | c.7247T>C p.L2416P | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53749094; called by muse, mutect2, varscan2
- ATR | c.6868T>C p.W2290R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV100637630; called by muse, mutect2, varscan2
- BICD1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55680270; called by muse, mutect2, varscan2
- CARNS1 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57056483; called by muse, mutect2, varscan2
- CGA | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100851647; called by muse, mutect2, varscan2
- DSCAM | c.1028A>G p.Q343R | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV101258957; called by muse, mutect2
- ERAP1 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | PolyPhen benign (0); catalogued as rs372808514; called by muse, mutect2, varscan2
- FCRL1 | c.410C>G p.A137G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100839707; called by muse, mutect2, varscan2
- HYDIN | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99861783; called by mutect2, varscan2
- IGF2BP1 | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99288199; called by muse, mutect2, varscan2
- ITGB4 | c.3862C>T p.L1288F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99563223; called by muse, mutect2, varscan2
- KIF20A | c.1564T>A p.S522T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV101203073; called by muse, mutect2, varscan2
- KIF26B | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV68572887; called by muse, mutect2
- LAMC1 | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99278856; called by muse, mutect2
- LRRC59 | c.885G>C p.E295D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99869330; called by muse, mutect2, varscan2
- MAMDC4 | c.1855G>T p.V619F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs191106356, COSV58075426; called by muse, mutect2, varscan2
- MMP16 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs202054317, COSV54154850; called by muse, mutect2, varscan2
- NUDT10 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs140448074, COSV100726777; called by muse, mutect2, varscan2
- PAPPA2 | c.2918T>C p.F973S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1409213233, COSV100867487, COSV62789890; called by muse, mutect2, varscan2
- PIP5K1A | c.929G>A p.R310H (on ENST00000368888 / NM_001135638.2; = p.R297H on NM_003557.3) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1242484794, COSV100576480; called by muse, mutect2, varscan2
- POTEF | c.2126T>C p.V709A | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV100664532; called by muse, mutect2, varscan2
- PPIL6 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101329645; called by muse, mutect2, varscan2
- RAD18 | c.700A>G p.R234G | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV53753300; called by muse, mutect2, varscan2
- RPTN | c.1236T>A p.S412R | Missense Mutation (SNP) | VAF 142/498 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV100285208; called by muse, mutect2, varscan2
- RSPH1 | c.461A>G p.H154R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1163971408, COSV99370268; called by muse, mutect2, varscan2
- SAP130 | c.2906T>G p.L969R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99384054; called by muse, mutect2, varscan2
- SMARCAL1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 24/37 reads (65%) | catalogued as COSV100619719; called by muse, mutect2, varscan2
- SP4 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs568588187, COSV56027661; called by muse, mutect2, varscan2
- STYXL2 | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs763985272, COSV54808034; called by muse, mutect2, varscan2
- SYNJ2 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1303843363, COSV62896194; called by muse, mutect2, varscan2
- TTN | c.49254C>A p.H16418Q (on ENST00000591111; = p.H8994Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | PolyPhen benign (0.024); catalogued as rs772133203, COSV100592179, COSV59979901; called by muse, mutect2, varscan2
- WASHC2A | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99254467; called by muse, mutect2, varscan2
- WWC1 | c.3236G>A p.G1079D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99514104; called by muse, mutect2, varscan2
- XYLT2 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs946429141, COSV99190514; called by muse, mutect2, varscan2
- ZNF230 | c.643_644insC p.E215Afs*13 | Frame Shift Ins (INS) | VAF 25/90 reads (28%) | catalogued as COSV101431885; called by mutect2, pindel, varscan2
- ZNF454 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.443); catalogued as rs778321557, COSV100194525; called by muse, mutect2, varscan2
- ZNF534 | c.229A>G p.R77G (on ENST00000332323 / NM_001143939.3; = p.R64G on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99989378; called by muse, mutect2
- CATSPERD | c.705_715del p.S236* | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- PCDH9 | c.2291_2301del p.L764Cfs*8 | Frame Shift Del (DEL) | VAF 28/47 reads (60%) | called by mutect2, pindel, varscan2
- PDE3A | c.2271_2273del p.T758del | In Frame Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- SLC6A7 | c.1088-3_1101del p.X363_splice | Splice Site (DEL) | VAF 16/67 reads (24%) | called by mutect2, varscan2
- ALDH1L2 | c.1731G>A p.L577= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV99310638; called by muse, mutect2, varscan2
- ATXN3L | c.933C>T p.H311= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs373799323, COSV101019290; called by muse, mutect2, varscan2
- CDK12 | c.1305A>G p.V435= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV101420334; called by mutect2, varscan2
- DDX19B | c.987G>T p.G329= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs766370234, COSV99849766; called by muse, mutect2, varscan2
- DST | c.6015G>A p.G2005= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV99750444; called by muse, mutect2, varscan2
- EHBP1 | c.3594G>A p.A1198= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1441090635, COSV99859895; called by mutect2, varscan2
- FLNC | c.675C>T p.A225= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs780730123, COSV100367568; called by muse, mutect2
- GABRB3 | c.1266G>A p.P422= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs377621777; called by mutect2, varscan2
- GMIP | c.1171A>C p.R391= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99179069; called by muse, mutect2, varscan2
- LSR | c.1932G>A p.R644= (on ENST00000361790; = p.R625= on NM_015925.6) | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99723247; called by muse, mutect2, varscan2
- NEB | c.12036T>C p.H4012= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs1287758552, COSV99414202; called by muse, mutect2, varscan2
- OR6K6 | c.792C>A p.A264= (on ENST00000368144; = p.A240= on NM_001005184.1) | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV100933775, COSV63743971; called by muse, mutect2, varscan2
- PLCE1 | c.5295C>A p.A1765= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99593217; called by muse, mutect2, varscan2
- PTPN22 | c.2241A>T p.T747= (on ENST00000359785 / NM_001193431.2; = p.T692= on NM_012411.5) | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100703358, COSV63084585; called by muse, mutect2, varscan2
- RANBP17 | c.3252C>T p.L1084= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs771836030, COSV101206019; called by muse, mutect2, varscan2
- ROBO2 | c.66G>A p.S22= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1404912865, COSV100163876; called by muse, mutect2
- TNR | c.3093C>T p.G1031= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99687239; called by muse, mutect2
- YWHAB | c.315A>G p.K105= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV62304817; called by muse, mutect2, varscan2
- AC024940.1 | n.98G>A | RNA (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- MPND | c.*2C>G | 3'UTR (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99514962; called by muse, mutect2, varscan2
- UBTFL2 | n.701A>T | RNA (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2
